Gene-level copy-number profile of tumor specimen HTMCP-02-04-01015-01A from CGCI case HTMCP-02-04-01015, project CGCI-HTMCP-LC (HIV+ Tumor Molecular Characterization Project - Lung Cancer). Sex at birth: female.
Specimen HTMCP-02-04-01015-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 8f07b724-6980-41fd-9448-a4f9fb719299.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HTMCP-02-04-01015-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,226 have no estimate.
https://portal.gdc.cancer.gov/files/0cd09401-9335-4ccd-905f-32836d6cdb90

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 166; copy number 1: 14,466; copy number 2: 41,596; copy number 3: 1,935; copy number 4: 176; copy number 5: 4; copy number 6: 13; copy number 7: 9; copy number 8: 8; copy number 10: 1; copy number 13: 1; copy number 14: 3; copy number 20: 1; copy number 28: 18.

Homozygous deletions (total copy number 0; autosomes only): 166 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:49,486,926–49,589,529, 12 genes: AC119751.3, ANKRD20A17P, AC119751.5, AC119751.2, AC119751.8, AC119751.7, MTCO3P42, AC119751.1, AC119751.6, SNX18P24, AC119751.4, SNX18P25.
- chr18:44,676,927–51,845,628, 146 genes (broad region; genes not listed).
- chr22:18,527,802–18,638,405, 8 genes: TMEM191B, PI4KAP1, AC023490.1, RN7SKP131, RIMBP3, Metazoa_SRP, SUSD2P2, CA15P2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 58 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr11:98,130,239–102,378,670, 34 genes, copy number 5–28: AP001317.1, AP003038.1, AP003715.1, AP002428.1, CNTN5, RN7SKP53, RPA2P3, RN7SL222P, PPIAP43, ARHGAP42-AS1, ARHGAP42, RN7SKP115, PGR, PGR-AS1, AP001533.1, TRPC6, MIR3920, AP003080.1, AP000776.1, ANGPTL5, CEP126, CFAP300, RNA5SP535, AP001527.1, AP001527.2, YAP1, AP000942.2, AP000942.1, AP000942.3, AP000942.4, RNU6-952P, AP000942.5, BIRC3, BIRC2.
- chr11:102,681,310–103,045,712, 16 genes, copy number 7–8: AP000851.2, MMP27, MMP8, WTAPP1, AP000619.1, AP000619.3, MMP10, MMP1, AP000619.2, MMP3, MMP12, BOLA3P1, RNU7-159P, MMP13, AP001486.3, AP001486.1.
- chr11:103,050,687–103,055,799, 1 gene, copy number 8: AP001486.2.
- chr11:104,445,868–104,609,498, 1 gene, copy number 6: LINC02552.
- chr20:19,212,642–19,722,926, 1 gene, copy number 5 (within-gene range 2–5): SLC24A3.
- chr20:19,756,390–20,056,046, 5 genes, copy number 6 (within-gene range 1–6): AL121761.1, RIN2, RPL12P12, NAA20, CRNKL1.

Autosomal genes at a single copy (total copy number 1): 12,122. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
